Gene-level copy-number profile of tumor specimen TCGA-EB-A3Y6-01A from TCGA case TCGA-EB-A3Y6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 56.4 years (20,605 days).
Specimen TCGA-EB-A3Y6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dd0ce005-54a1-4f3e-b2d3-1f6c0aec4804.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-EB-A3Y6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b8537aa4-8d85-4d57-9a65-91a3a276e230

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 17; copy number 2: 1,158; copy number 3: 5,154; copy number 4: 6,635; copy number 5: 15,654; copy number 6: 15,242; copy number 7: 9,843; copy number 8: 2,332; copy number 9: 41; copy number 10: 628; copy number 11: 1,214; copy number 12: 54; copy number 13: 91; copy number 14: 140; copy number 15: 36; copy number 16: 31; copy number 17: 93; copy number 19: 20; copy number 22: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A3Y6-01A-21D-A238-01): tumor purity 0.67, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,683 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,540,305–174,995,308, 789 genes, copy number 11–12 (within-gene range 11–13) (broad region; genes not listed).
- chr1:229,271,062–234,760,056, 110 genes, copy number 11 (broad region; genes not listed).
- chr1:234,837,976–234,838,069, 1 gene, copy number 11: RNY4P16.
- chr1:236,981,339–248,937,043, 262 genes, copy number 11 (broad region; genes not listed).
- chr7:7,066,964–7,067,045, 1 gene, copy number 11: MIR3683.
- chr11:72,754,729–73,142,318, 8 genes, copy number 12 (within-gene range 5–12): STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1.
- chr22:17,734,138–20,495,844, 142 genes, copy number 11–19 (broad region; genes not listed).
- chr22:20,689,929–22,432,465, 138 genes, copy number 11–14 (broad region; genes not listed).
- chr22:38,200,767–45,010,005, 232 genes, copy number 13–22 (within-gene range 10–22) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
